Gene-level copy-number profile of tumor specimen ALCH-B3D7-TTP1-A from ALCHEMIST case ALCH-B3D7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.4 years (27,159 days).
Specimen ALCH-B3D7-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9c6341e1-5d83-4960-aa28-a6fcdff03072.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3D7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,776 have no estimate.
https://portal.gdc.cancer.gov/files/9c04a2bc-5a5e-4ee9-a5ef-0c91a2ce7d3a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 110; copy number 1: 18,162; copy number 2: 35,546; copy number 3: 4,306; copy number 4: 269; copy number 5: 124; copy number 6: 126; copy number 7: 159; copy number 8: 15; copy number 9: 4; copy number 10: 13; copy number 11: 9; copy number 12: 1; copy number 16: 2; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): 110 genes in 53 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,211,340–1,214,153, 1 gene: TNFRSF4.
- chr1:1,317,581–1,318,689, 1 gene (within-gene range 0–3): AL139287.1.
- chr1:2,326,201–2,326,693, 1 gene (within-gene range 0–2): AL589739.1.
- chr1:12,847,377–13,032,130, 9 genes (within-gene range 0–1): HNRNPCL1, PRAMEF2, PRAMEF4, PRAMEF10, PRAMEF7, RNU6-1072P, PRAMEF29P, PRAMEF6, PRAMEF28P.
- chr1:13,060,869–13,062,229, 1 gene (within-gene range 0–1): HNRNPCL3.
- chr1:13,222,705–13,275,627, 4 genes: PRAMEF18, PRAMEF31P, PRAMEF5, PRAMEF32P.
- chr1:13,474,973–13,514,003, 1 gene (within-gene range 0–2): LRRC38.
- chr2:231,453,531–231,483,641, 2 genes (within-gene range 0–1): NCL, SNORA75.
- chr2:231,460,371–231,460,440, 1 gene (within-gene range 0–1): SNORD82.
- chr3:46,835,111–46,882,172, 1 gene (within-gene range 0–1): MYL3.
- chr3:48,625,723–48,635,493, 2 genes (within-gene range 0–2): SLC26A6, MIR6824.
- chr3:49,277,144–49,340,712, 1 gene (within-gene range 0–1): USP4.
- chr4:165,045,969–165,060,554, 2 genes: AC106872.6, TRIM75P.
- chr5:69,093,949–69,160,939, 4 genes: SLC30A5, AC010273.2, AC010273.1, SNORA50D.
- chr5:69,280,175–69,334,249, 3 genes: CCDC125, CFL1P5, CHCHD2P2.
- chr5:69,477,472–69,502,466, 2 genes (within-gene range 0–1): AC145146.1, RN7SL616P.
- chr5:138,083,990–138,139,443, 4 genes: WNT8A, NME5, RNU6-460P, RNU6-888P.
- chr6:73,241,314–73,417,566, 13 genes (within-gene range 0–1): KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43.
- chr6:73,523,618–73,570,596, 2 genes (within-gene range 0–1): AL121972.1, AL603910.1.
- chr11:62,646,848–62,665,210, 3 genes (within-gene range 0–1): INTS5, AP001458.2, C11orf98.
- chr12:2,954,240–2,954,338, 1 gene: RNU6-1315P.
- chr12:12,248,991–12,289,329, 2 genes (within-gene range 0–1): AC007621.3, RNU6-318P.
- chr12:12,568,201–12,568,776, 1 gene: AC092824.1.
- chr12:14,216,590–14,255,226, 4 genes: AC092112.1, MRPS18CP4, RNU6-491P, GNAI2P1.
- chr12:118,063,593–118,145,584, 3 genes (within-gene range 0–1): VSIG10, AC131238.1, PEBP1.
- chr13:27,960,918–27,969,315, 1 gene: CDX2.
- chr14:105,248,490–105,251,093, 1 gene (within-gene range 0–2): BTBD6.
- chr16:88,643,289–88,651,054, 1 gene: CYBA.
- chr16:89,919,165–89,938,761, 3 genes (within-gene range 0–5): AC092143.1, AC092143.2, TUBB3.
- chr16:90,004,871–90,019,890, 1 gene (within-gene range 0–1): DBNDD1.
- chr17:1,241,939–1,271,815, 2 genes: AC144836.1, BHLHA9.
- chr17:2,586,330–2,587,866, 1 gene: EIF4A1P9.
- chr17:3,565,444–3,663,103, 8 genes (within-gene range 0–1): TRPV1, AC027796.5, AC027796.3, AC027796.1, SHPK, AC027796.2, CTNS, AC027796.4.
- chr17:20,501,513–20,512,357, 2 genes: KRT16P3, AC015818.7.
- chr17:20,545,371–20,549,952, 1 gene (within-gene range 0–1): AC015818.8.
- chr17:20,576,667–20,580,911, 2 genes: AC015818.4, CDRT15L2.
- chr19:663,482–669,500, 1 gene: AC004156.1.
- chr20:51,902,291–51,905,030, 2 genes: RNU6-347P, RNU7-6P.
- chr20:52,110,344–52,111,049, 1 gene (within-gene range 0–2): ERP29P1.
- chr20:64,105,820–64,107,171, 1 gene: NPBWR2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 454 genes in 47 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,216,909–1,232,067, 1 gene, copy number 7: SDF4.
- chr1:1,242,446–1,251,334, 2 genes, copy number 8–16: C1QTNF12, AL162741.1.
- chr1:1,280,436–1,309,609, 3 genes, copy number 7–12 (within-gene range 2–12): SCNN1D, ACAP3, MIR6726.
- chr1:1,324,756–1,335,314, 2 genes, copy number 9: CPTP, TAS1R3.
- chr1:3,454,665–3,481,113, 1 gene, copy number 5: ARHGEF16.
- chr4:1,009,936–1,028,972, 2 genes, copy number 6–11: FGFRL1, AC019103.1.
- chr5:58,198–58,915, 1 gene, copy number 5: AC113430.1.
- chr5:710,355–850,986, 4 genes, copy number 5 (within-gene range 2–5): ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3.
- chr5:979,365–981,300, 1 gene, copy number 11: AC122719.2.
- chr5:1,594,626–1,611,467, 2 genes, copy number 5 (within-gene range 3–5): AC026412.3, AC091849.1.
- chr5:57,574,027–57,751,717, 2 genes, copy number 5: LINCR-0003, AC106822.1.
- chr6:31,353,872–31,366,898, 4 genes, copy number 5 (within-gene range 3–5): HLA-B, MIR6891, AL671883.2, DHFRP2.
- chr6:41,026,895–41,097,787, 4 genes, copy number 5 (within-gene range 4–5): UNC5CL, OARD1, TSPO2, APOBEC2.
- chr8:7,238,286–7,290,402, 7 genes, copy number 6: AF228730.3, OR7E125P, FAM90A15P, FAM90A3P, FAM90A4P, FAM90A13P, FAM90A5P.
- chr8:12,095,176–12,115,516, 2 genes, copy number 7: DEFB108D, ZNF705D.
- chr8:143,723,933–143,738,234, 2 genes, copy number 5–8: FAM83H, MIR4664.
- chr8:143,833,270–143,840,256, 2 genes, copy number 6: AC234917.1, AC234917.2.
- chr8:143,915,153–143,976,734, 2 genes, copy number 6 (within-gene range 6–15): PLEC, MIR661.
- chr8:144,078,002–144,086,216, 4 genes, copy number 5: AC109322.1, EXOSC4, MIR6847, GPAA1.
- chr9:136,494,433–136,617,181, 4 genes, copy number 5–6: NOTCH1, MIR4673, AL592301.1, LINC01451.
- chr12:22,409,237–22,690,665, 7 genes, copy number 5 (within-gene range 4–5): AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1.
- chr12:23,108,458–23,191,587, 2 genes, copy number 5 (within-gene range 4–5): AC087258.1, AC087235.2.
- chr12:23,529,504–24,562,544, 2 genes, copy number 5 (within-gene range 4–5): SOX5, AC087260.1.
- chr12:24,704,503–25,386,241, 18 genes, copy number 5: AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1.
- chr12:26,120,030–26,299,290, 4 genes, copy number 5 (within-gene range 4–5): BHLHE41, SSPN, AC022509.3, AC022509.5.
- chr12:29,412,474–29,497,686, 1 gene, copy number 5 (within-gene range 4–5): OVCH1.
- chr12:38,532,895–41,774,671, 34 genes, copy number 5–6: AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400.
- chr12:56,941,174–59,436,874, 82 genes, copy number 5–10 (broad region; genes not listed).
- chr12:63,271,404–75,511,636, 228 genes, copy number 5–11 (broad region; genes not listed).
- chr14:105,472,962–105,492,267, 3 genes, copy number 5–9 (within-gene range 3–9): CRIP2, CRIP1, AL928654.3.
- chr14:105,583,731–105,601,728, 2 genes, copy number 5 (within-gene range 2–5): IGHA2, IGHE.
- chr14:105,621,116–105,621,180, 1 gene, copy number 6: MIR8071-1.
- chr14:105,664,633–105,669,843, 1 gene, copy number 16 (within-gene range 2–16): IGHGP.
- chr16:543,277–553,847, 2 genes, copy number 6: MIR3176, Z97986.1.
- chr16:88,638,572–88,640,468, 1 gene, copy number 5: IL17C.
- chr17:20,512,560–20,517,479, 1 gene, copy number 6: KRT17P6.
- chr17:81,228,277–81,239,091, 1 gene, copy number 8 (within-gene range 3–8): TEPSIN.
- chr19:676,392–683,392, 1 gene, copy number 7: FSTL3.
- chr19:1,505,022–1,536,046, 3 genes, copy number 5–6: ADAMTSL5, PLK5, AC027307.1.
- chr22:20,348,758–20,354,387, 1 gene, copy number 7 (within-gene range 1–7): AC007731.5.

Autosomal genes at a single copy (total copy number 1): 15,349. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
